Gene-level copy-number profile of tumor specimen ALCH-B1QL-TTP1-B from ALCHEMIST case ALCH-B1QL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.9 years (22,258 days).
Specimen ALCH-B1QL-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3493e987-a855-41e9-a7cd-3a7f76b0d403.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1QL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/50286da5-6175-4313-8e4c-32fa267671af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,294; copy number 2: 55,163; copy number 3: 424; copy number 4: 12; copy number 6: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,369,136–25,375,845, 1 gene: ARNILA.
- chr3:52,812,962–52,835,729, 4 genes (within-gene range 0–1): ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr10:103,608,619–103,610,050, 1 gene (within-gene range 0–1): AL121929.2.
- chr11:70,477,277–70,477,592, 1 gene (within-gene range 0–1): AP001271.1.
- chr12:47,731,908–47,732,351, 1 gene (within-gene range 0–2): AC004241.2.
- chr14:64,704,102–64,750,249, 1 gene (within-gene range 0–2): PLEKHG3.
- chr16:28,239,693–28,240,668, 1 gene: GAPDHP35.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr19:56,189,570–56,197,920, 1 gene: ZSCAN5B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:67,939,750–67,944,131, 1 gene, copy number 6 (within-gene range 1–6): LCAT.
- chr21:44,107,373–44,131,181, 1 gene, copy number 11: PWP2.

Autosomal genes at a single copy (total copy number 1): 438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
